Somatic mutation profile of tumor specimen MMRF_1431_1_BM_CD138pos (aliquot MMRF_1431_1_BM_CD138pos_T1_KBS5U_L05543) from MMRF case MMRF_1431, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.3 years (27,515 days).
Specimen MMRF_1431_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f43939b1-ae77-4565-9d07-3656ed790df1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1431_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1431_1_PB_Whole_C2_KBS5U_L05563; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6811e38-88e0-4810-966e-95b64e2bfcc6

The open-access MAF lists 105 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 22, Intron 17, Silent 14, Nonsense Mutation 3, 5'UTR 2, RNA 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as rs1442456392; called by muse, mutect2, varscan2
- ACADSB | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100715352; called by muse, mutect2, varscan2
- ADCY2 | c.2344G>C p.A782P | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV100602445, COSV57897991; called by muse, mutect2, varscan2
- ADGRV1 | c.6856C>T p.R2286* | Nonsense Mutation (SNP) | VAF 39/195 reads (20%) | catalogued as CM0911269; called by muse, mutect2, varscan2
- ARHGEF18 | c.3233C>T p.S1078F (on ENST00000359920 / NM_001130955.2; = p.S974F on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.096); catalogued as COSV100149750, COSV60467359; called by muse, mutect2, varscan2
- CSMD1 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1037008169, COSV99064790; called by muse, mutect2
- DNAH17 | c.12423C>G p.I4141M | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99428447; called by muse, mutect2, varscan2
- ESPNL | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs751673854, COSV58036331; called by muse, mutect2, varscan2
- FREM1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.088); catalogued as COSV63087359; called by muse, mutect2, varscan2
- GABRG1 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1051514270, COSV54961028; called by muse, mutect2
- GPR156 | c.346A>G p.M116V | Missense Mutation (SNP) | VAF 172/321 reads (54%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs561697334; called by muse, mutect2, varscan2
- IGHV2-70 | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs369201986; called by muse, varscan2
- IGHV2-70 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376985995; called by mutect2, varscan2
- IGKV1D-8 | c.229C>G p.Q77E | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs367577669; called by muse, mutect2, varscan2
- JAG1 | c.473C>A p.S158* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as CM030051; called by muse, mutect2
- KRT28 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.577); catalogued as rs1011651056, COSV60683770; called by muse, mutect2, varscan2
- LRP2 | c.13207A>T p.S4403C | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV55547420; called by muse, mutect2, varscan2
- PRRT3 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.231); catalogued as rs560402876; called by muse, mutect2, varscan2
- PTEN | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.626); catalogued as CM001319, COSV64298024; called by muse, mutect2
- PTGIS | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs267605986, COSV54839772; called by muse, mutect2, varscan2
- TCF3 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs779358744, COSV53652361; called by muse, mutect2, varscan2
- TEKT1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs771322076; called by muse, mutect2, varscan2
- TFAP2A | c.175T>C p.Y59H (on ENST00000482890; = p.Y51H on NM_001032280.3) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV60235125; called by muse, mutect2
- TGM2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs967969723; called by muse, mutect2
- TIAM1 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.914); catalogued as COSV99732977; called by muse, mutect2, varscan2
- ZSCAN1 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.835); catalogued as rs764113791, COSV56601539, COSV56605865; called by muse, mutect2, varscan2
- AFF2 | c.1809A>C p.K603N | Missense Mutation (SNP) | VAF 82/90 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- AKNAD1 | c.1666T>G p.Y556D | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CHST13 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CNPY4 | c.623A>G p.D208G | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXL18 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HAL | c.1747G>T p.V583L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- HLA-DPA1 | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- LRRC66 | c.2452T>A p.F818I | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- LRSAM1 | c.325T>G p.L109V | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MELK | c.1757A>G p.H586R | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MMP2 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- MRO | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NCAM2 | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- OR51E2 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM15 | c.1376_1379del p.V459Efs*25 | Frame Shift Del (DEL) | VAF 44/222 reads (20%) | called by pindel, varscan2
- ST18 | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- TJP3 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM229A | c.524A>C p.K175T | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- TTN | c.53221G>A p.E17741K (on ENST00000591111; = p.E10317K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/125 reads (18%) | PolyPhen benign (0.169); called by muse, mutect2, varscan2
- USP20 | c.2674G>A p.V892M | Missense Mutation (SNP) | VAF 103/146 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- WDR49 | c.110C>A p.A37D (on ENST00000308378 / NM_001366158.1; = p.A378D on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CSMD1 | c.111G>A p.Q37= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- FAM161A | c.546A>G p.E182= | Silent (SNP) | VAF 68/140 reads (49%) | called by muse, mutect2, varscan2
- FAR2 | c.507G>A p.P169= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs138675198; called by muse, mutect2, varscan2
- GRIP2 | c.1287C>A p.P429= (on ENST00000619221; = p.P332= on NM_001080423.4) | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- IGKV4-1 | c.291C>T p.F97= | Silent (SNP) | VAF 26/30 reads (87%) | called by muse, mutect2, varscan2
- INTS1 | c.5427G>A p.Q1809= | Silent (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- NRG1 | c.519C>A p.T173= | Silent (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- OR14A16 | c.318A>T p.A106= | Silent (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- OXCT1 | c.138A>G p.P46= | Silent (SNP) | VAF 96/313 reads (31%) | called by muse, mutect2, varscan2
- SCN1A | c.132C>T p.D44= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as rs372758956; ClinVar: likely benign; called by muse, mutect2, varscan2
- SH3BP5 | c.630T>C p.P210= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- SLC4A2 | c.1185C>T p.P395= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs370012124; called by muse, mutect2, varscan2
- SLITRK3 | c.2034G>A p.V678= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as rs756708557, COSV53851528; called by muse, mutect2, varscan2
- UNKL | c.1665C>T p.A555= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs537408300, COSV50190125; called by muse, mutect2, varscan2
- AP001122.1 | n.573A>T | RNA (SNP) | VAF 36/246 reads (15%) | called by muse, mutect2, varscan2
- BAZ1A | c.1607-44A>G | Intron (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- CD163L1 | c.124+1816A>T | Intron (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- CYP27C1 | c.*1335G>A | 3'UTR (SNP) | VAF 13/87 reads (15%) | catalogued as rs1174544503; called by muse, mutect2, varscan2
- DIS3L2 | c.702+269A>G | Intron (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- DNAAF3 | c.*260A>G | 3'UTR (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- DSC2 | c.*1742A>G | 3'UTR (SNP) | VAF 16/118 reads (14%) | catalogued as rs1312444576; called by muse, mutect2, varscan2
- FAM107A | c.*2095C>T | 3'UTR (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- FAM174B | c.*89G>A | 3'UTR (SNP) | VAF 94/477 reads (20%) | catalogued as rs750567500; called by muse, mutect2, varscan2
- FBXO42 | c.*1281C>T | 3'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- GAL3ST2 | c.120-55C>T | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as rs1289995614; called by muse, varscan2
- HBD | c.-29+1328T>C | Intron (SNP) | VAF 89/130 reads (68%) | called by muse, mutect2, varscan2
- KLB | c.*2062G>A | 3'UTR (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- KLHL17 | c.-108G>A | 5'UTR (SNP) | VAF 18/27 reads (67%) | called by muse, mutect2, varscan2
- LDB2 | c.133-78_133-77del | Intron (DEL) | VAF 39/121 reads (32%) | called by mutect2, pindel, varscan2
- LST1 | c.20-104_20-103del | Intron (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- MIR548AE1 | n.31C>T | RNA (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- MPRIP | c.2163+2782C>G | Intron (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- NACC2 | c.*1464G>T | 3'UTR (SNP) | VAF 35/149 reads (23%) | catalogued as rs1564214266; called by muse, mutect2, varscan2
- NCAPD2 | c.263-157A>C | Intron (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- NKAIN2 | c.*1063T>G | 3'UTR (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- NUDT5 | c.*1937A>G | 3'UTR (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- NWD1 | c.*313C>T | 3'UTR (SNP) | VAF 13/86 reads (15%) | catalogued as rs946814955; called by muse, mutect2, varscan2
- PCDH15 | c.2868+996T>C | Intron (SNP) | VAF 14/52 reads (27%) | called by muse, varscan2
- PCDH15 | c.2868+883A>T | Intron (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- PCDH15 | c.2868+36A>T | Intron (SNP) | VAF 115/368 reads (31%) | called by muse, mutect2, varscan2
- PHACTR1 | c.1447+2170T>C | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- PLEKHG4 | c.499+46C>T | Intron (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- POLR3G | c.*2065A>G | 3'UTR (SNP) | VAF 61/217 reads (28%) | called by muse, mutect2, varscan2
- PPARA | c.*4952T>A | 3'UTR (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- PPP1R12A | c.*925T>C | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- PRPS1 | c.-16A>C | 5'UTR (SNP) | VAF 40/44 reads (91%) | called by muse, mutect2, varscan2
- PTCD3 | c.1779-605G>A | Intron (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2
- SH2D1B | c.*209A>C | 3'UTR (SNP) | VAF 38/94 reads (40%) | called by muse, mutect2, varscan2
- SLC9A2 | c.*1752C>T | 3'UTR (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- SOX9 | c.*5G>A | 3'UTR (SNP) | VAF 104/233 reads (45%) | called by muse, mutect2, varscan2
- SSBP2 | c.*3174C>G | 3'UTR (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- STON1 | chr2:48530061 G>T | 5'Flank (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- TMEM245 | c.*1799C>G | 3'UTR (SNP) | VAF 56/164 reads (34%) | called by muse, mutect2, varscan2
- TNPO2 | c.-13-157G>A | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, varscan2
- TRPV2 | c.1990-136C>T | Intron (SNP) | VAF 5/8 reads (63%) | catalogued as rs181922302; called by muse, mutect2, varscan2
- TUFM | c.*89G>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ZNF197 | c.*2756A>C | 3'UTR (SNP) | VAF 73/118 reads (62%) | called by muse, mutect2, varscan2
- ZNF385D | c.*1890G>T | 3'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
